Gene-level copy-number profile of tumor specimen TCGA-DX-A8BU-01A from TCGA case TCGA-DX-A8BU, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant fibrous histiocytoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 58.8 years (21,470 days).
Specimen TCGA-DX-A8BU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.3f50fa02-5bd6-44e2-86db-fec0ea239f53.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A8BU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ea73f3ff-7bfc-4a84-b151-dd5da78759fc

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 72; copy number 1: 355; copy number 2: 11,078; copy number 3: 14,595; copy number 4: 14,178; copy number 5: 10,561; copy number 6: 3,603; copy number 7: 3,667; copy number 8: 1,236; copy number 9: 120; copy number 10: 62; copy number 11: 151; copy number 13: 38; copy number 16: 15; copy number 25: 68; copy number 33: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A8BU-01A-11D-A37B-01): tumor purity 0.93, ploidy 1.73, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 72 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:950,849–1,367,613, 3 genes (within-gene range 0–2): SNTG2, AC114808.1, AC114808.2.
- chr2:16,199,203–16,432,702, 7 genes: AC142283.1, AC010745.1, AC010745.2, AC010745.3, AC010745.5, AC010745.4, AC010880.1.
- chr13:48,232,612–50,910,764, 62 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 462 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:176,068,042–176,114,537, 3 genes, copy number 9: EI24P1, AC104640.2, AC117434.1.
- chr5:18,547,312–21,196,860, 19 genes, copy number 9–11: RN7SL58P, LINC02100, UBE2V1P12, AC025768.1, AC114981.1, Metazoa_SRP, AC106744.1, AC106744.2, RPL32P14, HSPD1P15, CDH18, AC093303.1, AC094103.1, CDH18-AS1, LINC02146, LINC02241, AC138938.1, AC140168.1, AC140172.1.
- chr6:6,144,084–6,995,727, 18 genes, copy number 9–10: F13A1, MIR7853, MIR5683, LY86-AS1, SNAPC5P1, AL162719.1, CNN3P1, LY86, AL031123.2, AL031123.3, AL031123.1, AL031123.4, AL031123.5, AL136361.1, BTF3P7, AL158817.1, RN7SL554P, AL139390.1.
- chr6:7,481,094–8,102,559, 15 genes, copy number 9: HNRNPLP1, AL138878.1, AL138878.2, AL031058.1, DSP, SNRNP48, AL390026.1, BMP6, TXNDC5, BLOC1S5-TXNDC5, AL096800.1, PIP5K1P1, BLOC1S5, EEF1E1-BLOC1S5, EEF1E1.
- chr6:39,792,298–40,276,237, 7 genes, copy number 11: DAAM2, AL592158.1, DAAM2-AS1, MOCS1, TUBBP9, FO393411.1, AL139275.2.
- chr6:41,494,853–48,214,794, 173 genes, copy number 11–13 (within-gene range 7–13) (broad region; genes not listed).
- chr6:52,246,460–54,840,855, 69 genes, copy number 9–16 (broad region; genes not listed).
- chr18:7,455,844–8,414,304, 12 genes, copy number 9: AP001095.1, PTPRM, AP000897.2, AP000897.1, U3, AP005900.1, AC006566.2, AC006566.1, AP001094.3, AP001094.2, AP001094.1, COP1P1.
- chr18:10,124,588–11,149,569, 22 genes, copy number 9: AP005271.1, AP005209.2, AP005209.1, AP006219.1, AP006219.2, LINC01254, AP006219.3, APCDD1, NAPG, AP001099.1, LINC01887, AP001180.3, CCDC58P1, AP001180.2, AP001180.5, PMM2P1, AP001180.1, PIEZO2, AP001180.4, KIAA0895LP1, MIR6788, AP005120.1.
- chr19:30,228,290–32,829,580, 39 genes, copy number 10 (within-gene range 6–10): ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1, TSHZ3, LINC01791, AC025809.1, AC025809.2, AC008992.1, AC008794.1, LINC02841, AC011525.1, AC011525.2, RNA5SP471, RNU6-967P, LINC01837, LINC01533, LINC01782, AC011518.1, AC074139.1, RNA5SP472, ZNF507, AC007773.1, DPY19L3, PDCD5, ANKRD27, SNORA68B, RPS12P31, RN7SL789P, AC008474.1, RGS9BP, AC008736.1, NUDT19, AC008736.2, TDRD12, AC008805.1.
- chr19:43,912,624–44,033,110, 9 genes, copy number 10 (within-gene range 7–10): ZNF45, ZNF221, ZNF155, AC006213.4, AC006213.5, AC006213.1, ZNF230, AC067968.2, ZNF222.
- chr22:20,314,238–21,371,945, 68 genes, copy number 25 (broad region; genes not listed).
- chr22:32,801,705–33,145,861, 5 genes, copy number 33 (within-gene range 4–33): TIMP3, Z83846.1, LINC01640, Z82198.1, Z82198.3.
- chr22:33,164,063–33,436,669, 3 genes, copy number 33: Z82198.2, Z82173.1, MIR4764.

Autosomal genes at a single copy (total copy number 1): 351. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
